Somatic mutation profile of tumor specimen TARGET-10-PARLFI-09A (aliquot TARGET-10-PARLFI-09A-01D) from TARGET case TARGET-10-PARLFI, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 14.0 years (5,102 days).
Specimen TARGET-10-PARLFI-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 240f56dc-acbe-43b2-95b5-7ce77457abaf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARLFI-14A (Bone Marrow Normal), aliquot TARGET-10-PARLFI-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d288a7d0-3f70-4d99-b732-67e110cc7335

The open-access MAF lists 13 somatic variants for this specimen: 6 protein-altering or splice-affecting, 4 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 4, RNA 2, Frame Shift Ins 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- OBSCN | c.13783C>T p.R4595C | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781461411; called by muse, mutect2, varscan2
- RASGRP2 | c.1046G>T p.S349I | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.017); catalogued as COSV62449205; called by muse, mutect2, varscan2
- RASSF4 | c.497G>A p.R166Q | Missense Mutation (SNP) | VAF 45/207 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs11540205; called by muse, mutect2, varscan2
- RABIF | c.238G>A p.V80M | Missense Mutation (SNP) | VAF 33/75 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RP1 | c.6266A>G p.E2089G | Missense Mutation (SNP) | VAF 5/69 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.454); called by muse, mutect2
- TRDD3 | c.12_13insCC p.*5Pfs*? | Frame Shift Ins (INS) | VAF 7/35 reads (20%) | called by mutect2, varscan2
- CYREN | c.450C>T p.Y150= | Silent (SNP) | VAF 23/107 reads (21%) | catalogued as rs1223068931, COSV51966879; called by muse, mutect2, varscan2
- FUT9 | c.420T>A p.T140= | Silent (SNP) | VAF 83/149 reads (56%) | called by muse, mutect2, varscan2
- MAZ | c.1125C>T p.F375= | Silent (SNP) | VAF 14/68 reads (21%) | catalogued as rs1311129114, COSV50714366; called by muse, mutect2, varscan2
- TRDD3 | c.13delinsCCT p.*5P | Silent (INS) | VAF 8/38 reads (21%) | called by mutect2*, pindel, varscan2*
- AC109486.1 | n.53C>T | RNA (SNP) | VAF 33/85 reads (39%) | catalogued as rs558919185; called by muse, mutect2, varscan2
- OTOA | c.1731-63dup | Intron (INS) | VAF 18/47 reads (38%) | called by mutect2, pindel, varscan2
- RPLP0P6 | n.186C>T | RNA (SNP) | VAF 15/73 reads (21%) | called by muse, mutect2, varscan2
